TCGA case TCGA-W5-AA2T — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8944fe2a-e32f-4898-a2c5-fb6751f602a4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 1,220 days (3.3 years).

Diagnoses (6)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 64.5 years (23,560 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Child pugh classification: A; Ishak fibrosis score: 0 - No Fibrosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 56 days; Days to treatment end: 205 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Radiation Therapy, NOS.
2. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: Head, face or neck, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Bone, NOS. Age at diagnosis: 65.3 years (23,855 days); Days to diagnosis: 295 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 296 days; Residual disease: R0.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease.
4. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Bone, NOS. Age at diagnosis: 66.0 years (24,121 days); Days to diagnosis: 561 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 907 days (2.5 years); Residual disease: RX.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease.
5. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Lung, NOS. Age at diagnosis: 67.0 years (24,456 days); Days to diagnosis: 896 days (2.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
6. Recurrence of diagnosis 1 (Cholangiocarcinoma), site: Bone, NOS. Age at diagnosis: 67.2 years (24,553 days); Days to diagnosis: 993 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 1,021 days (2.8 years); Residual disease: RX.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Ablation or Embolization, NOS, for recurrent disease; Organ Transplantation to Liver, for recurrent disease; Pharmaceutical Therapy, NOS, for recurrent disease.

Follow-up (6 entries)
- Day 295 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 295 days.
- Day 561 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 561 days (1.5 years).
- Day 896 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to recurrence: 896 days (2.5 years).
- Day 993 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to recurrence: 993 days (2.7 years).
- Days to follow up: 1,220 days (3.3 years); Disease response: With Tumor.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 33 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 55.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Platelets 274 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Total Bilirubin 0.4 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Creatinine 0.6 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.1].
- Albumin 4.4 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 62 kg; Height: 155 cm; BMI: 25.8.
- Timepoint category: Prior to Diagnosis; Risk factors: Tobacco, Smoking.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA2T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-W5-AA2T-01A-01-TS1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 60; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-W5-AA2T-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W5-AA2T-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-W5-AA2T-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-W5-AA2T-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Definitive surgical procedure: Extended Lobectomy.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: nose; Other malignancy histological type: basal cell carcinoma.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,220 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,220 days; disease-free interval: event (new tumor event after initially disease-free), 295 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 295 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W5-AA2T-01A-12D-A416-01): tumor purity 0.85, ploidy 3.55, whole-genome doublings 1.
